Somatic mutation profile of tumor specimen C3N-00217-02 (aliquot CPT0090570010) from CPTAC case C3N-00217, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 59.8 years (21,854 days).
Specimen C3N-00217-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53859753-6fcc-45fb-8915-2c61ba87194b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00217-31 (Blood Derived Normal), aliquot CPT0092500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7b252f1-7742-4ce2-a786-ad3196ea952b

The open-access MAF lists 840 somatic variants for this specimen: 571 protein-altering or splice-affecting, 163 silent, 106 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 488, Silent 163, Nonsense Mutation 43, Intron 39, RNA 26, 3'UTR 15, Splice Site 15, 5'UTR 12, Frame Shift Del 12, Splice Region 9, 5'Flank 8, 3'Flank 6.

Variants (750 of 840; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF4A | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555817727, CM1111342; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 98/183 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.1930G>A p.G644R | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1481472005; called by muse, mutect2, varscan2
- ABCC9 | c.1641del p.I548* | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | catalogued as COSV53966850; called by mutect2, pindel, varscan2
- ACSBG1 | c.1790C>A p.A597D | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51907024; called by muse, mutect2, varscan2
- ADGRB1 | c.1093G>T p.V365L | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV60103731; called by muse, mutect2, varscan2
- ADGRL2 | c.1560C>A p.N520K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99590963; called by muse, mutect2, varscan2
- APOB | c.9785C>A p.P3262Q | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV99265604; called by muse, mutect2, varscan2
- APOB | c.2633C>A p.S878Y | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51947467; called by muse, mutect2, varscan2
- ATR | c.4988C>T p.T1663I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs984341860; called by muse, mutect2, varscan2
- ATXN2L | c.2047A>G p.T683A | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs571133202, COSV57365332; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs754132810, COSV99959060; called by muse, mutect2, varscan2
- BRWD3 | c.4253G>T p.R1418L | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64751502; called by muse, mutect2, varscan2
- C6 | c.1333C>G p.R445G | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54706799; called by muse, mutect2, varscan2
- CABLES1 | c.1840G>A p.A614T (on ENST00000256925 / NM_001100619.2; = p.A349T on NM_138375.2) | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as rs757746929; called by muse, mutect2, varscan2
- CACNA1I | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1400949374, COSV60820119; called by muse, mutect2, varscan2
- CAMK2G | c.1631A>G p.N544S (on ENST00000423381 / NM_001367518.1; = p.N481S on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs1270413038; called by muse, mutect2, varscan2
- CCDC168 | c.3613G>A p.V1205I | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.262); catalogued as rs774656078, COSV70555297; called by muse, mutect2, varscan2
- CCKBR | c.832C>A p.R278S | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs144317623, COSV58099630, COSV58103840; called by muse, mutect2, varscan2
- CCP110 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV66817989; called by muse, mutect2, varscan2
- CD33 | c.649G>C p.A217P | Missense Mutation (SNP) | VAF 110/223 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99220713; called by muse, mutect2, varscan2
- CDH12 | c.776T>A p.L259H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101203188; called by muse, mutect2, varscan2
- CDH23 | c.3179G>T p.R1060L | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV54937509; called by muse, mutect2, varscan2
- CDH4 | c.1206del p.E403Kfs*13 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | catalogued as COSV64649510; called by mutect2, pindel
- CDH7 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV59888974; called by muse, mutect2, varscan2
- CEP162 | c.3630G>T p.R1210S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100002653; called by muse, mutect2, varscan2
- CHST8 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.313); catalogued as rs746174725; called by muse, mutect2, varscan2
- CLVS1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV57970800; called by muse, mutect2
- CNTNAP5 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs890816163, COSV70496411, COSV70507161; called by muse, mutect2, varscan2
- COL6A5 | c.6310G>T p.A2104S (on ENST00000312481; = p.A2100S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55205506; called by muse, mutect2, varscan2
- CPXCR1 | c.616C>A p.R206S | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.372); catalogued as COSV52161231; called by muse, mutect2, varscan2
- CR2 | c.887C>A p.S296* | Nonsense Mutation (SNP) | VAF 108/190 reads (57%) | catalogued as COSV65508603; called by muse, varscan2
- CRACD | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as rs752589045; called by muse, mutect2, varscan2
- CRACD | c.1426C>A p.R476S | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV51718305; called by muse, mutect2, varscan2
- CRYZ | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777656845; called by muse, mutect2
- CSMD1 | c.6753C>A p.F2251L (on ENST00000520002; = p.F2250L on NM_033225.6) | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100153589, COSV59290346; called by muse, mutect2, varscan2
- CSN2 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 93/349 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs1003669682, COSV61992393; called by muse, mutect2, varscan2
- CUL4B | c.1812G>T p.E604D | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60691050; called by muse, mutect2
- CXCR2 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV59280818; called by muse, mutect2, varscan2
- DMRT2 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs769974746; called by muse, mutect2, varscan2
- DNAH7 | c.5401A>G p.T1801A | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56758227; called by muse, mutect2, varscan2
- ENTHD1 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV57325214; called by muse, mutect2, varscan2
- EPHA10 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60402661; called by muse, mutect2, varscan2
- ERCC6 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100875822; called by muse, mutect2, varscan2
- EVI5 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1311854813, COSV64828914; called by muse, mutect2, varscan2
- FAM135B | c.3699C>A p.F1233L | Missense Mutation (SNP) | VAF 188/336 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52703933, COSV52705298; called by muse, mutect2, varscan2
- FAM50A | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 79/349 reads (23%) | catalogued as COSV99340980; called by muse, mutect2, varscan2
- FAT3 | c.2260G>C p.D754H | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53116526; called by muse, mutect2, varscan2
- FBXW7 | c.751C>G p.L251V (on ENST00000281708 / NM_001349798.2; = p.L171V on NM_018315.5) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV99657472; called by muse, mutect2, varscan2
- FCGR3A | c.318C>A p.I106= | Splice Region (SNP) | VAF 190/537 reads (35%) | catalogued as COSV63458984; called by muse, mutect2, varscan2
- FLG | c.7003C>A p.Q2335K | Missense Mutation (SNP) | VAF 384/571 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.308); catalogued as rs747753029; called by mutect2, varscan2
- FLNC | c.6397C>A p.R2133S | Missense Mutation (SNP) | VAF 85/551 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100367728; called by muse, mutect2, varscan2
- FLNC | c.7486G>T p.V2496F | Missense Mutation (SNP) | VAF 152/334 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs200295337, COSV57952568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT1 | c.1091G>C p.R364P | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55356903; called by muse, mutect2, varscan2
- FOXC1 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1317322703; called by muse, mutect2, varscan2
- FOXN3 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 160/284 reads (56%) | catalogued as rs1305475097; called by muse, mutect2, varscan2
- FREM2 | c.7820G>T p.G2607V | Missense Mutation (SNP) | VAF 76/359 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV54846703; called by muse, mutect2, varscan2
- FUT9 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100133427, COSV56142443; called by muse, mutect2, varscan2
- GABRA3 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 220/523 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100943448; called by muse, mutect2, varscan2
- GABRG3 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61514526; called by muse, mutect2, varscan2
- GABRR2 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101298988; called by muse, mutect2, varscan2
- GALNT15 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV60216703; called by muse, mutect2, varscan2
- GALNT6 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100695599; called by muse, mutect2, varscan2
- GIMAP4 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV55431295, COSV55433809; called by muse, mutect2, varscan2
- GPR137B | c.553T>A p.W185R | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV63991703; called by muse, mutect2, varscan2
- GRM8 | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV58834505; called by muse, mutect2, varscan2
- HERC2 | c.11170G>C p.V3724L | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs149280444; called by muse, mutect2, varscan2
- HIRIP3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1396224621; called by muse, mutect2, varscan2
- HMCN1 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 42/423 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54948120; called by muse, mutect2
- HNRNPH2 | c.1242G>T p.Q414H | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV57266660; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 88/655 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1459421177; called by muse, varscan2
- IGHV3-48 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.025); catalogued as rs782433324; called by muse, mutect2
- IL20RB | c.212A>T p.Q71L | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59048101; called by muse, mutect2, varscan2
- INAVA | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV66256142; called by muse, mutect2, varscan2
- IRF8 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 110/282 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV99235936; called by muse, mutect2, varscan2
- ISLR | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.677); catalogued as COSV51435573; called by muse, mutect2, varscan2
- ITIH6 | c.1850G>A p.S617N | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54491281; called by muse, mutect2, varscan2
- KCNH2 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.025); catalogued as rs1336631581; called by muse, mutect2, varscan2
- KCNIP3 | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54669548; called by muse, mutect2, varscan2
- KDR | c.2099G>A p.W700* | Nonsense Mutation (SNP) | VAF 74/262 reads (28%) | catalogued as COSV55778996; called by muse, mutect2, varscan2
- KIAA0319 | c.2482C>A p.Q828K | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs908493842, COSV65498957; called by muse, mutect2
- KIF26B | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV101314054; called by muse, mutect2, varscan2
- LACTB2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1315237504; called by muse, mutect2
- LAMA1 | c.6091G>T p.G2031W | Missense Mutation (SNP) | VAF 114/424 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV67534114; called by muse, mutect2, varscan2
- LARP7 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs199621386; called by muse, mutect2, varscan2
- LCORL | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1179182723; called by muse, mutect2, varscan2
- LLGL2 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781542922, COSV51418588; called by muse, mutect2, varscan2
- LTBP1 | c.3292G>T p.E1098* (on ENST00000404816 / NM_206943.4; = p.E772* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 61/200 reads (31%) | catalogued as rs148779103; called by muse, mutect2, varscan2
- MAGEB10 | c.917G>T p.W306L | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1038138861; called by muse, mutect2, varscan2
- MAGEB10 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV63313044; called by muse, mutect2, varscan2
- MAGEC3 | c.212C>A p.S71* | Nonsense Mutation (SNP) | VAF 31/174 reads (18%) | catalogued as rs1180569197, COSV74217328; called by muse, mutect2, varscan2
- MAGEC3 | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV53576884; called by muse, mutect2, varscan2
- MAP9 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs749611120, COSV60906381; called by muse, mutect2, varscan2
- MAP9 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV60903623; called by muse, mutect2, varscan2
- MAPK3 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV53772811; called by muse, mutect2
- MGAM2 | c.1044G>C p.L348F | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1302226664; called by muse, mutect2, varscan2
- MYT1 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1394463309; called by muse, mutect2, varscan2
- NALCN | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as COSV51922964; called by muse, mutect2, varscan2
- NRXN2 | c.1918C>A p.P640T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV55461635; called by muse, mutect2, varscan2
- ONECUT1 | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV100009077; called by muse, mutect2, varscan2
- OR10H3 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs144612710; called by muse, mutect2, varscan2
- OR10J3 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59954068; called by muse, mutect2, varscan2
- OR1Q1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs764018659, COSV52917322; called by muse, mutect2, varscan2
- OR2L3 | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100741946; called by muse, mutect2, varscan2
- OR4D5 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774267550; called by muse, mutect2, varscan2
- OR51E2 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 138/356 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs565364663, COSV67806631, COSV67806703, COSV67807925; called by muse, mutect2, varscan2
- OR5H1 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs376299906; called by muse, mutect2, varscan2
- OR9G4 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265015, COSV100265223; called by muse, mutect2, varscan2
- OTOP3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.733); catalogued as rs745958249, COSV60913295; called by muse, mutect2, varscan2
- PCDH15 | c.3984-1G>T p.X1328_splice | Splice Site (SNP) | VAF 48/180 reads (27%) | catalogued as COSV57301113, COSV57303763; called by muse, mutect2, varscan2
- PCDHA7 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.334); catalogued as COSV100971544, COSV65346583; called by muse, mutect2, varscan2
- PCDHA7 | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65343037; called by muse, mutect2, varscan2
- PCDHGA9 | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs552765425; called by muse, mutect2, varscan2
- PCNT | c.3309G>T p.Q1103H | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV64028671; called by muse, mutect2, varscan2
- PDE3A | c.2125C>A p.R709S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV62967617; called by muse, mutect2, varscan2
- PDE4DIP | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100516493; called by muse, varscan2
- PDK3 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.331); catalogued as COSV104431282; called by muse, mutect2, varscan2
- PES1 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV58828748; called by muse, mutect2, varscan2
- PKD1L3 | c.2624C>A p.S875Y | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV58666262; called by muse, mutect2, varscan2
- PLCXD3 | c.532del p.E178Kfs*4 | Frame Shift Del (DEL) | VAF 79/257 reads (31%) | catalogued as COSV60609095; called by mutect2, pindel, varscan2
- POTEC | c.285G>T p.R95S | Missense Mutation (SNP) | VAF 301/729 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.983); catalogued as rs767315474; called by muse, mutect2, varscan2
- POTEG | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 284/870 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs767401356; called by muse, varscan2
- PPP1R3F | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs1193283245, COSV50018811; called by muse, mutect2, varscan2
- PRDM9 | c.1376G>T p.R459M | Missense Mutation (SNP) | VAF 129/438 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.496); catalogued as COSV99691117; called by muse, mutect2, varscan2
- PRLHR | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776987466, COSV99493053; called by muse, mutect2, varscan2
- PRODH2 | c.448G>A p.A150T (on ENST00000301175; = p.A74T on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as rs377260631; called by muse, mutect2, varscan2
- PRTG | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1445356691, COSV101221458, COSV66837501; called by muse, mutect2, varscan2
- PSMA8 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs371854509, COSV57605327; called by muse, mutect2, varscan2
- PTF1A | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 125/372 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64735346; called by muse, mutect2, varscan2
- RALB | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV55602474; called by muse, mutect2, varscan2
- RAPGEF6 | c.2927A>C p.Y976S | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57247909; called by muse, mutect2, varscan2
- RASA2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759141778, COSV53937672; called by muse, mutect2, varscan2
- RELN | c.2461C>G p.P821A | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV58999547; called by muse, mutect2, varscan2
- RIMS2 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 237/394 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68501699, COSV68503237; called by muse, mutect2, varscan2
- RTF1 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67478418; called by muse, mutect2
- RTL3 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs1478875238; called by muse, mutect2, varscan2
- RTL8A | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV66188316; called by muse, mutect2, varscan2
- SEMA3E | c.2264A>T p.Q755L | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV57082409; called by muse, mutect2, varscan2
- SEMA6D | c.441C>A p.Y147* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100317254; called by muse, mutect2
- SERPINB7 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV60534051; called by muse, mutect2, varscan2
- SHANK2 | c.5083C>T p.P1695S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.423); catalogued as rs1255983619; called by muse, varscan2
- SHANK2 | c.2243G>T p.R748L | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV53591868; called by muse, mutect2, varscan2
- SIGLEC10 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs150721520; called by muse, mutect2, varscan2
- SLC17A6 | c.1151T>A p.V384E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54136009; called by muse, mutect2, varscan2
- SLC17A6 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV54134971; called by muse, mutect2, varscan2
- SLC9C2 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62945570; called by muse, mutect2, varscan2
- SLCO4C1 | c.1177T>G p.S393A | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV60518551; called by muse, mutect2, varscan2
- SLITRK1 | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 89/168 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV65677402, COSV65677692; called by muse, mutect2, varscan2
- SNTG1 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.974); catalogued as rs1162600367; called by muse, mutect2, varscan2
- SNURF | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.341); catalogued as rs1172109294, COSV57593868; called by muse, mutect2, varscan2
- SNX32 | c.454C>G p.R152G | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV57450118; called by muse, mutect2, varscan2
- SPSB4 | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60149368; called by muse, mutect2, varscan2
- SPTA1 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as rs931070390, COSV100934710; called by muse, mutect2
- SRMS | c.914T>C p.M305T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1239546326; called by muse, mutect2, varscan2
- ST6GAL2 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 41/134 reads (31%) | PolyPhen benign (0.015); catalogued as COSV64528458; called by muse, mutect2, varscan2
- STUB1 | c.96G>C p.Q32H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs766618211; called by muse, mutect2, varscan2
- SYT4 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV99673673; called by muse, mutect2, varscan2
- TECRL | c.635C>G p.T212R | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV101168978, COSV67089885; called by muse, mutect2, varscan2
- TFAP2D | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99145909; called by muse, mutect2, varscan2
- TLDC2 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV53430983; called by muse, mutect2, varscan2
- TMEM187 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 57/234 reads (24%) | catalogued as rs782264046; called by muse, mutect2, varscan2
- TMEM89 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100258438; called by muse, mutect2, varscan2
- TRAV13-1 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 113/198 reads (57%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.843); catalogued as rs532318430; called by muse, mutect2, varscan2
- TRIM2 | c.1474G>T p.V492L (on ENST00000437508; = p.V519L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.844); catalogued as COSV58639503; called by muse, mutect2, varscan2
- TRPA1 | c.1027C>A p.R343S | Missense Mutation (SNP) | VAF 145/313 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV51566060; called by muse, mutect2, varscan2
- TRPC5 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53289485; called by muse, mutect2, varscan2
- TSC22D2 | c.1709C>G p.T570R | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.806); catalogued as COSV62622872; called by muse, mutect2, varscan2
- TTC34 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as rs965920436; called by muse, mutect2, varscan2
- UGT2B4 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 32/118 reads (27%) | catalogued as COSV59315714; called by muse, mutect2, varscan2
- UNC5D | c.323-1G>C p.X108_splice | Splice Site (SNP) | VAF 24/104 reads (23%) | catalogued as COSV54801509; called by muse, varscan2
- UNC93A | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100023245; called by muse, mutect2, varscan2
- VRTN | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.729); catalogued as rs773509797, COSV56441764; called by muse, mutect2, varscan2
- ZDHHC11 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 99/859 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1272931783; called by muse, mutect2, varscan2
- ZFHX4 | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 144/282 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs1022368685, COSV99259797; called by muse, mutect2, varscan2
- ZNF568 | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71278861; called by muse, mutect2, varscan2
- ZNF648 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV60569801; called by muse, mutect2, varscan2
- ZNF703 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 25/369 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as rs756014282; called by muse, mutect2
- ZNF730 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV74168399; called by muse, mutect2, varscan2
- ZNF835 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 154/352 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs751662049; called by muse, mutect2, varscan2
- ZNF844 | c.286dup p.T96Nfs*9 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs1434070576; called by mutect2, varscan2
- ZNF99 | c.1027T>G p.C343G | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101233717; called by muse, mutect2, varscan2
- A2M | c.4093del p.L1365* | Frame Shift Del (DEL) | VAF 50/215 reads (23%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11292C>A p.S3764R | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ABCA5 | c.2963G>A p.S988N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA6 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AC024598.1 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM2B | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ACTN2 | c.2428A>C p.T810P | Missense Mutation (SNP) | VAF 474/820 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, varscan2
- ADAM19 | c.1930A>T p.R644W | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS1 | c.2625G>T p.Q875H | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ADAMTS10 | c.2865+7C>G | Splice Region (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.1924C>A p.L642I | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ADAMTSL4 | c.3112C>G p.P1038A | Missense Mutation (SNP) | VAF 137/752 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ADCY2 | c.1498T>C p.S500P | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADGB | c.2841G>C p.W947C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ADGRA3 | c.473+1G>T p.X158_splice | Splice Site (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- AFG3L2 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 77/249 reads (31%) | called by muse, mutect2, varscan2
- AHNAK | c.16916G>T p.G5639V | Missense Mutation (SNP) | VAF 93/168 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AHNAK2 | c.4696G>T p.V1566L | Missense Mutation (SNP) | VAF 93/804 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKT2 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 94/284 reads (33%) | called by muse, mutect2, varscan2
- ALOXE3 | c.767A>T p.H256L | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ANO1 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ANPEP | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APOB | c.12614C>A p.P4205Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARGFX | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP23 | c.4447G>T p.A1483S | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF4 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ATP2B1 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, varscan2
- ATP5F1A | c.1280A>T p.K427M | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ATP7B | c.221A>T p.K74M | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ATP8A2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AVPR2 | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 95/197 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- BCOR | c.2123C>A p.T708N | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BIRC6 | c.1035-1G>T p.X345_splice | Splice Site (SNP) | VAF 54/153 reads (35%) | called by muse, mutect2, varscan2
- BMS1 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 105/350 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- C1orf87 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- C2orf16 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C4orf54 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C5orf58 | c.45A>C p.K15N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2
- CABIN1 | c.493A>C p.I165L | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CACNA1C | c.1615C>T p.L539F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CACNA1S | c.927G>T p.W309C | Missense Mutation (SNP) | VAF 193/369 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNA2D2 | c.2936+3G>A | Splice Region (SNP) | VAF 68/154 reads (44%) | called by muse, mutect2, varscan2
- CAD | c.3399+1G>C p.X1133_splice | Splice Site (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.838C>A p.R280S | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CATSPERG | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CCDC144A | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCDC168 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CCDC3 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 60/230 reads (26%) | called by muse, mutect2, varscan2
- CCL23 | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCM2L | c.1120T>C p.C374R | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CCNYL2 | n.801G>T | Splice Region (SNP) | VAF 16/42 reads (38%) | called by muse, varscan2
- CD163 | c.3343+1G>A p.X1115_splice | Splice Site (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- CD1C | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 134/250 reads (54%) | called by muse, mutect2, varscan2
- CD70 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDH22 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDH23 | c.1135-2A>G p.X379_splice | Splice Site (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- CDHR1 | c.640-1G>T p.X214_splice | Splice Site (SNP) | VAF 93/392 reads (24%) | called by muse, mutect2, varscan2
- CDIPT | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- CEP250 | c.656G>A p.C219Y | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.748); called by muse, mutect2
- CHD8 | c.5850G>A p.M1950I (on ENST00000646647 / NM_001170629.2; = p.M1671I on NM_020920.4) | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CHRNB2 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CLCN6 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- COG4 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 121/597 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- COL4A1 | c.3892C>A p.P1298T | Missense Mutation (SNP) | VAF 121/488 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A1 | c.3437C>G p.P1146R | Missense Mutation (SNP) | VAF 177/448 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.2726C>A p.P909H | Missense Mutation (SNP) | VAF 114/367 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- COL6A2 | c.680A>T p.D227V | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CPXCR1 | c.503A>C p.Q168P | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRB2 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CROCC | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CSAG3 | c.314+2T>A p.X105_splice | Splice Site (SNP) | VAF 56/316 reads (18%) | called by mutect2, varscan2
- CSF2RA | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CSMD1 | c.8587C>T p.P2863S (on ENST00000520002; = p.P2862S on NM_033225.6) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CSMD3 | c.8336C>G p.S2779* (on ENST00000297405 / NM_001363185.1; = p.S2610* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 32/364 reads (9%) | called by muse, mutect2
- CTSA | c.1360-2A>T p.X454_splice | Splice Site (SNP) | VAF 102/387 reads (26%) | called by muse, mutect2, varscan2
- CYP27C1 | c.801C>T p.T267= | Splice Region (SNP) | VAF 70/212 reads (33%) | called by muse, mutect2, varscan2
- CYP2S1 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 92/293 reads (31%) | called by muse, mutect2, varscan2
- CYP4F22 | c.1179G>T p.K393N | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAB2 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 62/186 reads (33%) | called by muse, mutect2, varscan2
- DAO | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 92/370 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF12L2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DCSTAMP | c.84del p.F29Lfs*31 | Frame Shift Del (DEL) | VAF 284/604 reads (47%) | called by pindel, varscan2
- DCSTAMP | c.299C>A p.A100E | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, varscan2
- DDN | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2
- DDX59 | c.1487A>T p.Y496F | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DDX60 | c.4440G>T p.M1480I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DEFB125 | c.52_54delinsT p.T18* | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | called by pindel, varscan2*
- DES | c.352C>G p.R118G | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.908); called by muse, varscan2
- DLG1 | c.1542G>T p.S514= | Splice Region (SNP) | VAF 58/246 reads (24%) | called by muse, mutect2, varscan2
- DNAH3 | c.7708G>T p.G2570W | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.4109T>C p.M1370T | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- DNAH6 | c.12347C>T p.A4116V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DNAH8 | c.3109T>A p.S1037T | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNER | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- DNMBP | c.1712A>T p.D571V | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DOCK4 | c.2944A>T p.T982S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DOHH | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DQX1 | c.1667T>A p.L556* | Nonsense Mutation (SNP) | VAF 72/223 reads (32%) | called by muse, mutect2, varscan2
- DSC2 | c.2335G>C p.G779R | Missense Mutation (SNP) | VAF 45/452 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- DSC3 | c.2279G>T p.S760I | Missense Mutation (SNP) | VAF 78/339 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DSC3 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 94/382 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DSG1 | c.1700T>A p.L567* | Nonsense Mutation (SNP) | VAF 140/583 reads (24%) | called by muse, mutect2, varscan2
- DYSF | c.2498C>A p.T833K | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGFL6 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EGFL6 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by mutect2, varscan2
- ELMO1 | c.724T>A p.Y242N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EN1 | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ENSA | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 162/437 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ERICH3 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ERICH3 | c.117G>T p.L39= | Splice Region (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- EVX1 | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM151A | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FAM153B | c.547G>T p.G183C (on ENST00000253490; = p.G106C on NM_001265615.1) | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.709); called by muse, varscan2
- FAM186B | c.96+8C>T | Splice Region (SNP) | VAF 28/204 reads (14%) | called by muse, mutect2, varscan2
- FAM187A | c.-1599+1G>T | Splice Site (SNP) | VAF 80/292 reads (27%) | called by muse, mutect2, varscan2
- FAM205A | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- FAM205A | c.1382C>A p.P461H | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- FAT4 | c.3217T>G p.S1073A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FAT4 | c.8099G>T p.G2700V | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.8763G>T p.R2921S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBP2 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FBXL6 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 48/448 reads (11%) | called by muse, mutect2, varscan2
- FLNA | c.1845del p.P616Hfs*60 | Frame Shift Del (DEL) | VAF 107/436 reads (25%) | called by mutect2, pindel, varscan2
- FMN1 | c.3264G>T p.E1088D (on ENST00000616417 / NM_001277313.2; = p.E865D on NM_001103184.4) | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- FPGT | c.1423A>G p.R475G | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM2 | c.7819G>T p.G2607* | Nonsense Mutation (SNP) | VAF 74/357 reads (21%) | called by muse, mutect2, varscan2
- FRMPD1 | c.3145C>A p.H1049N | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD2 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSHR | c.1643G>T p.C548F | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- FSIP2 | c.11884C>A p.H3962N | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUT7 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GABRA5 | c.756C>A p.H252Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GALC | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 109/172 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAS2L3 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- GATA6 | c.29dup p.L10Ffs*108 | Frame Shift Ins (INS) | VAF 46/197 reads (23%) | called by mutect2, pindel, varscan2
- GGN | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GIMAP4 | c.41C>A p.T14K | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJD3 | c.406T>A p.Y136N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GJD3 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- GK2 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GP2 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 113/291 reads (39%) | called by muse, mutect2, varscan2
- GPR173 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GPRASP2 | c.790A>T p.T264S | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRASP2 | c.1746G>T p.W582C | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GRB14 | c.1605T>G p.C535W | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIA3 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK3 | c.2565+7C>A | Splice Region (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- GRIN3A | c.2626G>A p.G876S | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GUCA1B | c.208-1G>T p.X70_splice | Splice Site (SNP) | VAF 51/486 reads (10%) | called by muse, mutect2, varscan2
- HERC5 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- HOXB13 | c.398A>T p.Y133F | Missense Mutation (SNP) | VAF 83/470 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HTR4 | c.577G>C p.A193P | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.4016T>A p.L1339Q | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYDIN | c.9128T>A p.L3043* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- IFNA17 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- IFT172 | c.4660-1G>A p.X1554_splice | Splice Site (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- IGDCC3 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 39/91 reads (43%) | called by muse, mutect2, varscan2
- IGDCC4 | c.2044G>T p.G682C | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- IGHV3-23 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 288/960 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- IGHV4-34 | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 142/791 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- IGKV1-8 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 127/437 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV1-9 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- IGKV1D-13 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 111/590 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IGKV3-15 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IGSF1 | c.3630C>A p.D1210E | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IL10RB | c.419A>C p.Y140S | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IL1A | c.569A>T p.Q190L | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- INCENP | c.2302G>T p.A768S (on ENST00000394818 / NM_001040694.2; = p.A764S on NM_020238.3) | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- INTS1 | c.4253G>T p.G1418V | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- INTS6 | c.2042G>A p.G681E | Missense Mutation (SNP) | VAF 60/347 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IRF2BP2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRF3 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IRX4 | c.1520T>A p.L507H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ISLR2 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ITGA4 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- ITGAM | c.2666A>T p.K889M (on ENST00000648685 / NM_001145808.2; = p.K888M on NM_000632.4) | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ITGB5 | c.2189G>T p.S730I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JRK | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KCNA1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KEAP1 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- KHDRBS3 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2
- KIAA0100 | c.58T>C p.F20L | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, varscan2
- KIAA1109 | c.13688G>A p.R4563K | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA1109 | c.14605G>T p.V4869L | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- KIAA1328 | c.467G>T p.R156I | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- KIAA1549L | c.1085C>T p.S362F (on ENST00000321505; = p.S659F on NM_012194.3) | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- KMT2D | c.12681G>T p.M4227I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, varscan2
- KRT6B | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 174/568 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KRTAP11-1 | c.403G>T p.G135* | Nonsense Mutation (SNP) | VAF 37/210 reads (18%) | called by muse, mutect2, varscan2
- LCOR | c.3310G>T p.E1104* | Nonsense Mutation (SNP) | VAF 80/279 reads (29%) | called by muse, mutect2, varscan2
- LEFTY1 | c.987C>A p.S329R | Missense Mutation (SNP) | VAF 207/408 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- LILRB4 | c.363C>A p.Y121* | Nonsense Mutation (SNP) | VAF 82/142 reads (58%) | called by muse, mutect2, varscan2
- LPAR3 | c.1028G>T p.S343I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1 | c.8138G>T p.W2713L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRTM4 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6G6E | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 167/266 reads (63%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAGEB17 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MAGEB3 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MANSC1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP1A | c.3038C>A p.S1013Y | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K1 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MOSPD2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MSL3 | c.1162C>A p.L388M (on ENST00000312196 / NM_078629.4; = p.L222M on NM_006800.4) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MT2A | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 121/354 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTUS2 | c.1148G>C p.G383A | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.6541C>A p.L2181I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MUC3A | c.8308C>A p.P2770T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MVK | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 163/551 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MVK | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 128/527 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MXRA5 | c.1087T>A p.L363M | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MYH13 | c.2126G>A p.C709Y | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYO18B | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- MYO3A | c.2376A>T p.E792D | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYO3B | c.2821G>T p.D941Y | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NAALADL1 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- NALCN | c.1111G>C p.G371R | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NAMPT | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- NAV3 | c.6774G>T p.M2258I (on ENST00000397909 / NM_001024383.2; = p.M2236I on NM_014903.6) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NAV3 | c.6775G>T p.D2259Y (on ENST00000397909 / NM_001024383.2; = p.D2237Y on NM_014903.6) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAN | c.2635G>T p.G879W | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- NCOR1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NDUFA3 | c.130A>C p.M44L | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NEDD4 | c.3672A>G p.I1224M (on ENST00000508342 / NM_001284338.1; = p.I805M on NM_006154.4) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- NEK3 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NEO1 | c.4336G>T p.A1446S | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NETO2 | c.1298del p.R433Pfs*39 | Frame Shift Del (DEL) | VAF 74/286 reads (26%) | called by mutect2, pindel, varscan2
- NLRP7 | c.2671G>T p.G891C (on ENST00000340844 / NM_206828.3; = p.G863C on NM_139176.3) | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NOTCH1 | c.5746del p.Q1916Rfs*65 | Frame Shift Del (DEL) | VAF 120/352 reads (34%) | called by mutect2, pindel, varscan2
- NRXN1 | c.3738C>A p.F1246L | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- NRXN1 | c.3522G>C p.L1174F | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- NUMBL | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); called by muse, mutect2
- NUP54 | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- OGFOD1 | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGFR | c.1800G>T p.E600D | Missense Mutation (SNP) | VAF 158/533 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, varscan2
- OLFML2B | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 137/250 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR11G2 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR13C5 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T12 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 55/505 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, varscan2
- OR2T12 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 57/497 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- OR2T2 | c.826T>A p.S276T | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2T34 | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- OR4C5 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OR4K13 | c.673G>T p.V225F | Missense Mutation (SNP) | VAF 185/336 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR51B5 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR51G2 | c.497T>C p.F166S | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR51G2 | c.408C>A p.H136Q | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, varscan2
- OR52A5 | c.506del p.L169Rfs*20 | Frame Shift Del (DEL) | VAF 71/213 reads (33%) | called by mutect2, pindel, varscan2
- OR52E2 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR52E4 | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- OR5D13 | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, varscan2
- OTOR | c.196A>T p.I66F | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PACSIN2 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- PARN | c.1809G>T p.E603D | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH12 | c.2777C>G p.S926* | Nonsense Mutation (SNP) | VAF 76/301 reads (25%) | called by muse, mutect2, varscan2
- PCDH18 | c.6C>A p.H2Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA3 | c.854T>G p.M285R | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); called by muse, mutect2
- PCDHA7 | c.1603G>C p.V535L | Missense Mutation (SNP) | VAF 238/804 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDHB10 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 79/428 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); called by mutect2, varscan2
- PCDHB11 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDHB13 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCDHB9 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 52/704 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PCDHGA2 | c.482A>T p.D161V | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCDHGA2 | c.575C>A p.P192Q | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- PCLO | c.7849G>T p.E2617* | Nonsense Mutation (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- PGK1 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 41/241 reads (17%) | called by muse, mutect2, varscan2
- PHACTR3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PHLPP1 | c.2129T>A p.V710D | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- PIGG | c.1808G>T p.G603V (on ENST00000453061 / NM_001127178.3; = p.G595V on NM_017733.4) | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PKD1L3 | c.2827G>T p.A943S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2
- PLA1A | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PLA1A | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCG2 | c.875C>A p.T292K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- PLG | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNB2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.141); called by muse, mutect2
- PNLIPRP2 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- POF1B | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- POM121L2 | c.2141C>G p.P714R | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- PPP1R15B | c.1698C>A p.Y566* | Nonsense Mutation (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- PPP1R3G | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 32/154 reads (21%) | called by muse, mutect2, varscan2
- PPP3CA | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRAMEF8 | c.980G>T p.R327M | Missense Mutation (SNP) | VAF 158/654 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2
- PRAMEF8 | c.130T>A p.F44I | Missense Mutation (SNP) | VAF 99/522 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM9 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 98/364 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PREX1 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRICKLE2 | c.2322A>T p.R774S (on ENST00000295902; = p.R718S on NM_198859.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PRKACG | c.667T>A p.W223R | Missense Mutation (SNP) | VAF 137/364 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKX | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- PRSS37 | c.584C>A p.T195N | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, varscan2
- PSMA1 | c.571G>C p.G191R | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSRC1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRQ | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PYCR2 | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 137/228 reads (60%) | called by muse, mutect2, varscan2
- RALGAPB | c.2162G>A p.G721D | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAPGEF6 | c.813G>T p.L271F | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASAL2 | c.3069G>C p.K1023N | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RASIP1 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM19 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- RBM45 | c.1363G>T p.V455L (on ENST00000616198 / NM_001365579.1; = p.V453L on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGS2 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 33/254 reads (13%) | called by muse, mutect2, varscan2
- RIMS2 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 285/528 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RLIM | c.126A>C p.E42D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF157 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- RNF213 | c.8222C>G p.T2741S | Missense Mutation (SNP) | VAF 68/505 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- RNF225 | c.848T>A p.L283Q | Missense Mutation (SNP) | VAF 229/477 reads (48%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- ROR2 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- RPH3A | c.577G>C p.E193Q (on ENST00000389385 / NM_001143854.2; = p.E189Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- RTL9 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RYR3 | c.3416G>T p.G1139V | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL3 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, varscan2
- SAMD9 | c.1078A>G p.R360G | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SBF1 | c.1199A>G p.H400R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- SEC31B | c.2625G>T p.L875F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SERINC1 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINB7 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, varscan2
- SETBP1 | c.3028A>G p.T1010A | Missense Mutation (SNP) | VAF 116/467 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SGK1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.078); called by muse, mutect2
- SIM1 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SIN3A | c.568T>A p.Y190N | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKIV2L | c.2657A>T p.Q886L | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC10A2 | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 114/455 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC10A4 | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC10A4 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A11 | c.1813_1815delinsAA p.R605Kfs*3 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by pindel, varscan2*
- SLC7A4 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SLC8A1 | c.1644T>A p.H548Q | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SNTG2 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SNX7 | c.322delinsTTT p.T108Ffs*4 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | called by pindel, varscan2*
- SOGA1 | c.4039G>T p.E1347* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- SPEG | c.5842G>C p.V1948L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SSX5 | c.433C>A p.L145I (on ENST00000347757 / NM_175723.1; = p.L186I on NM_021015.4) | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STON2 | c.1416C>G p.H472Q (on ENST00000649389 / NM_001366849.2; = p.H415Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/371 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- STOX2 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SYNE1 | c.558G>T p.K186N (on ENST00000367255 / NM_182961.4; = p.K193N on NM_033071.3) | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SYP | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SYT13 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SYT13 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SYTL4 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SYTL5 | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- TAF3 | c.1569G>C p.K523N | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TCF4 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- TENT5B | c.913A>C p.M305L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TFDP3 | c.337C>A p.R113S | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TIGD5 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLE4 | c.634A>T p.S212C | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- TMEM185B | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2
- TMEM38A | c.84T>G p.S28R | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TMPRSS11B | c.1198T>C p.Y400H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMPRSS11B | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNKS2 | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV3-1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TRIM46 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 118/377 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TRIM50 | c.653C>A p.T218N | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TRIM58 | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); called by muse, mutect2
- TRPC5 | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRPM6 | c.5503A>T p.R1835* | Nonsense Mutation (SNP) | VAF 54/280 reads (19%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2218T>C p.S740P | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TVP23B | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UBE3A | c.336A>C p.K112N | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UBQLN2 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- UGT2B7 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- UROC1 | c.660T>A p.H220Q | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- USF3 | c.2367C>A p.N789K | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- USP3 | c.256A>T p.M86L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- VAC14 | c.1223T>A p.L408H | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VEZT | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- WDFY4 | c.6727A>T p.K2243* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- XG | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2
- XIRP2 | c.186C>A p.S62R (on ENST00000628543; = p.S237R on NM_152381.6) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- XIRP2 | c.1631G>T p.R544M (on ENST00000628543; = p.R719M on NM_152381.6) | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XIRP2 | c.6300C>A p.N2100K (on ENST00000628543; = p.N2275K on NM_152381.6) | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR3 | c.1179G>T p.M393I | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- XKR4 | c.271G>C p.A91P | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB33 | c.722C>G p.T241R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZBTB33 | c.1947T>A p.N649K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZFAND3 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF202 | c.1476G>A p.W492* | Nonsense Mutation (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- ZNF407 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZNF407 | c.3083C>G p.S1028C | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF449 | c.1385C>A p.P462H | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF485 | c.928A>T p.S310C | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF549 | c.74G>A p.G25D (on ENST00000376233 / NM_001199295.2; = p.G12D on NM_153263.2) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); called by muse, varscan2
- ZNF628 | c.1363A>G p.K455E | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ZNF679 | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF709 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF804B | c.2049C>A p.S683R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZP4 | c.977A>T p.N326I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); called by muse, mutect2
- ZSCAN18 | c.469A>T p.M157L | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZSCAN4 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ZXDB | c.329del p.G110Vfs*8 | Frame Shift Del (DEL) | VAF 27/187 reads (14%) | called by mutect2, pindel, varscan2
- ABCC1 | c.1698C>T p.A566= | Silent (SNP) | VAF 35/194 reads (18%) | catalogued as rs1406360168; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2934C>G p.P978= | Silent (SNP) | VAF 63/298 reads (21%) | called by muse, mutect2, varscan2
- ADGRA2 | c.1512G>T p.L504= | Silent (SNP) | VAF 53/814 reads (7%) | called by muse, mutect2
- ADGRB1 | c.636C>A p.P212= | Silent (SNP) | VAF 110/187 reads (59%) | called by muse, mutect2, varscan2
- AHNAK2 | c.10839C>A p.A3613= | Silent (SNP) | VAF 392/598 reads (66%) | catalogued as rs768951245; called by muse, mutect2, varscan2
- AKT2 | c.1401G>A p.R467= | Silent (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- APOB | c.2634C>A p.S878= | Silent (SNP) | VAF 67/256 reads (26%) | called by muse, mutect2, varscan2
- AQP6 | c.339G>A p.V113= | Silent (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.2955T>G p.A985= (on ENST00000398564; = p.A960= on NM_014629.4) | Silent (SNP) | VAF 120/239 reads (50%) | catalogued as rs1307004976; called by muse, mutect2, varscan2
- ARSH | c.1317G>A p.K439= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ATP2B3 | c.3285G>T p.R1095= | Silent (SNP) | VAF 51/248 reads (21%) | called by muse, mutect2, varscan2
- BCAN | c.372G>T p.L124= | Silent (SNP) | VAF 66/110 reads (60%) | called by muse, mutect2, varscan2
- BTBD16 | c.1140G>T p.V380= | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as rs747685592; called by muse, mutect2, varscan2
- C1orf87 | c.1080G>T p.L360= | Silent (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- C2orf16 | c.5280T>C p.S1760= | Silent (SNP) | VAF 94/602 reads (16%) | called by muse, mutect2, varscan2
- CACNA1E | c.6843G>T p.G2281= (on ENST00000367573 / NM_001205293.3; = p.G2238= on NM_000721.4) | Silent (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2, varscan2
- CAD | c.3816G>T p.A1272= | Silent (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- CADM3 | c.1176C>T p.D392= (on ENST00000368125 / NM_001127173.3; = p.D426= on NM_021189.5) | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV63672184; called by muse, mutect2, varscan2
- CCL23 | c.312C>A p.T104= | Silent (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2, varscan2
- CDH5 | c.2181G>T p.T727= | Silent (SNP) | VAF 303/598 reads (51%) | catalogued as rs746556861, COSV58517524; called by muse, mutect2, varscan2
- CENPF | c.6012G>T p.V2004= | Silent (SNP) | VAF 28/292 reads (10%) | called by muse, mutect2
- CFAP46 | c.6723C>T p.D2241= | Silent (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- CLEC16A | c.876C>T p.Y292= | Silent (SNP) | VAF 56/130 reads (43%) | catalogued as rs201374731; called by muse, mutect2, varscan2
- CLRN2 | c.24G>T p.A8= | Silent (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- CMPK2 | c.243G>A p.P81= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2
- CREB3L1 | c.1278A>G p.L426= | Silent (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2
- CSMD3 | c.11052C>A p.T3684= (on ENST00000297405 / NM_001363185.1; = p.T3515= on NM_052900.3) | Silent (SNP) | VAF 50/512 reads (10%) | called by muse, mutect2
- CXCR2 | c.645C>A p.P215= | Silent (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- CYP24A1 | c.969C>A p.L323= | Silent (SNP) | VAF 106/300 reads (35%) | catalogued as COSV53773914; called by muse, mutect2, varscan2
- DCAF8L1 | c.18C>A p.G6= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2
- DENND2A | c.1155C>T p.D385= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as rs375091774; called by muse, mutect2, varscan2
- DGKI | c.2085G>T p.L695= | Silent (SNP) | VAF 40/290 reads (14%) | called by muse, mutect2, varscan2
- DIRAS2 | c.312C>A p.I104= | Silent (SNP) | VAF 84/429 reads (20%) | catalogued as COSV65370512; called by muse, mutect2, varscan2
- DNAH11 | c.1512C>T p.V504= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- DUOX2 | c.1536G>T p.R512= | Silent (SNP) | VAF 117/345 reads (34%) | called by muse, mutect2, varscan2
- EPHA3 | c.2160C>T p.V720= | Silent (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- ERCC6L | c.555C>A p.T185= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- ERFE | c.486G>T p.P162= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs533645800; called by muse, mutect2, varscan2
- ESPL1 | c.4512C>A p.I1504= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV57763709; called by muse, mutect2, varscan2
- EVX1 | c.798G>A p.A266= | Silent (SNP) | VAF 46/201 reads (23%) | catalogued as rs747551402, COSV56085581; called by muse, mutect2, varscan2
- F5 | c.3825C>G p.P1275= | Silent (SNP) | VAF 233/481 reads (48%) | called by muse, mutect2, varscan2
- FAM171A2 | c.177C>A p.A59= | Silent (SNP) | VAF 58/184 reads (32%) | called by muse, mutect2, varscan2
- FAM205A | c.1383C>A p.P461= | Silent (SNP) | VAF 26/195 reads (13%) | called by muse, mutect2, varscan2
- FAM220A | c.486G>T p.P162= | Silent (SNP) | VAF 56/239 reads (23%) | catalogued as COSV57625877; called by mutect2, varscan2
- FER1L5 | c.33T>A p.I11= | Silent (SNP) | VAF 48/163 reads (29%) | catalogued as COSV62616938; called by muse, mutect2, varscan2
- FLI1 | c.849G>T p.L283= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as COSV55645541; called by muse, mutect2, varscan2
- FNDC1 | c.3498C>A p.P1166= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV51948247, COSV99794752; called by muse, mutect2, varscan2
- FOXR2 | c.153C>A p.V51= | Silent (SNP) | VAF 31/236 reads (13%) | catalogued as COSV100189350; called by muse, mutect2, varscan2
- FSIP2 | c.14181T>A p.A4727= | Silent (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- GABRB3 | c.456G>A p.G152= | Silent (SNP) | VAF 58/365 reads (16%) | catalogued as COSV54660641, COSV54663781; called by muse, mutect2, varscan2
- GALNT14 | c.582T>A p.T194= | Silent (SNP) | VAF 57/193 reads (30%) | called by muse, mutect2, varscan2
- GJA3 | c.348G>A p.K116= | Silent (SNP) | VAF 96/298 reads (32%) | called by muse, mutect2, varscan2
- GP2 | c.237A>C p.S79= | Silent (SNP) | VAF 114/296 reads (39%) | called by muse, mutect2, varscan2
- GPR150 | c.450G>T p.A150= | Silent (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- GPRC5B | c.390C>G p.G130= | Silent (SNP) | VAF 76/186 reads (41%) | called by muse, mutect2, varscan2
- GRM1 | c.732C>T p.F244= | Silent (SNP) | VAF 53/246 reads (22%) | called by muse, mutect2, varscan2
- GRM1 | c.1644G>T p.T548= | Silent (SNP) | VAF 80/296 reads (27%) | called by muse, mutect2, varscan2
- HEPACAM | c.522C>A p.T174= | Silent (SNP) | VAF 114/287 reads (40%) | called by muse, mutect2, varscan2
- HEPH | c.3360G>A p.L1120= (on ENST00000343002; = p.L853= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/372 reads (13%) | called by muse, mutect2, varscan2
- HIF3A | c.603T>A p.P201= (on ENST00000377670 / NM_152795.4; = p.P132= on NM_022462.4) | Silent (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- HOOK1 | c.1188G>A p.A396= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs370702196; called by muse, mutect2, varscan2
- HPN | c.799C>T p.L267= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, varscan2
- HS6ST3 | c.202C>A p.R68= | Silent (SNP) | VAF 36/52 reads (69%) | called by muse, mutect2, varscan2
- HTR3C | c.915C>G p.T305= | Silent (SNP) | VAF 60/207 reads (29%) | catalogued as rs935297084; called by muse, mutect2, varscan2
- IGKV2-30 | c.21C>A p.L7= | Silent (SNP) | VAF 63/240 reads (26%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.702C>T p.A234= | Silent (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- KCNA5 | c.204T>A p.P68= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- KCNJ9 | c.804C>T p.D268= | Silent (SNP) | VAF 67/106 reads (63%) | catalogued as COSV63632356; called by muse, mutect2, varscan2
- KIAA0586 | c.2544G>A p.V848= (on ENST00000619416 / NM_001244190.2; = p.V787= on NM_014749.5) | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs374585380; called by muse, mutect2, varscan2
- KIAA2013 | c.249A>G p.V83= | Silent (SNP) | VAF 33/239 reads (14%) | called by muse, mutect2, varscan2
- KIF1A | c.33G>T p.R11= | Silent (SNP) | VAF 46/114 reads (40%) | called by muse, varscan2
- KIF26A | c.4170C>A p.V1390= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs562461621; called by muse, mutect2, varscan2
- L1CAM | c.966G>T p.R322= | Silent (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- LCP2 | c.168G>A p.K56= | Silent (SNP) | VAF 31/278 reads (11%) | called by muse, mutect2, varscan2
- LEP | c.429G>A p.E143= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as rs1213817089; called by muse, mutect2, varscan2
- LHX2 | c.1155G>C p.V385= | Silent (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- LRRC4C | c.435A>G p.V145= | Silent (SNP) | VAF 33/248 reads (13%) | called by muse, mutect2, varscan2
- MAP1B | c.4848G>T p.P1616= | Silent (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
- MDC1 | c.1410C>G p.V470= | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as COSV64528031; called by muse, mutect2, varscan2
- MMP16 | c.492T>C p.P164= | Silent (SNP) | VAF 48/268 reads (18%) | called by muse, mutect2, varscan2
- MROH7 | c.3216G>T p.R1072= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV100273680; called by muse, mutect2, varscan2
- MSX2 | c.186G>T p.A62= | Silent (SNP) | VAF 58/210 reads (28%) | called by muse, mutect2, varscan2
- MTR | c.3462C>T p.G1154= | Silent (SNP) | VAF 46/507 reads (9%) | called by muse, mutect2
- MUC17 | c.9549C>T p.T3183= | Silent (SNP) | VAF 51/138 reads (37%) | catalogued as COSV60281492; called by muse, mutect2, varscan2
- MUTYH | c.849G>T p.G283= | Silent (SNP) | VAF 89/476 reads (19%) | catalogued as rs771290019; ClinVar: likely benign; called by muse, mutect2, varscan2
- MVK | c.462A>C p.A154= | Silent (SNP) | VAF 127/525 reads (24%) | called by muse, mutect2, varscan2
- MYH1 | c.51C>A p.L17= | Silent (SNP) | VAF 75/195 reads (38%) | called by muse, mutect2, varscan2
- MYH15 | c.2346G>A p.L782= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- MYH3 | c.5151G>T p.L1717= | Silent (SNP) | VAF 142/334 reads (43%) | called by muse, mutect2, varscan2
- MYH3 | c.102C>T p.A34= | Silent (SNP) | VAF 154/352 reads (44%) | catalogued as rs773129491; called by muse, varscan2
- MYO16 | c.798C>A p.G266= | Silent (SNP) | VAF 47/198 reads (24%) | called by muse, mutect2, varscan2
- MYO18B | c.1002G>A p.K334= | Silent (SNP) | VAF 47/225 reads (21%) | catalogued as COSV59128302; called by muse, mutect2, varscan2
- MYO7B | c.3480G>T p.A1160= | Silent (SNP) | VAF 84/285 reads (29%) | called by muse, mutect2, varscan2
- MYOCD | c.2397T>C p.Y799= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as rs1402894191; called by muse, mutect2, varscan2
- NCR1 | c.229C>A p.R77= | Silent (SNP) | VAF 137/531 reads (26%) | catalogued as COSV52555296; called by muse, mutect2, varscan2
- NEUROD1 | c.396T>C p.S132= | Silent (SNP) | VAF 75/348 reads (22%) | called by muse, mutect2, varscan2
- NOX5 | c.750G>A p.V250= | Silent (SNP) | VAF 37/171 reads (22%) | called by muse, mutect2, varscan2
- NPAS3 | c.279C>T p.I93= (on ENST00000356141 / NM_001164749.2; = p.I63= on NM_022123.3) | Silent (SNP) | VAF 88/430 reads (20%) | called by muse, mutect2, varscan2
- NPC1L1 | c.687G>T p.V229= | Silent (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- OLFM1 | c.891C>T p.P297= (on ENST00000371793 / NM_001282611.2; = p.P279= on NM_014279.5) | Silent (SNP) | VAF 60/190 reads (32%) | called by muse, mutect2, varscan2
- OR51M1 | c.102C>T p.G34= | Silent (SNP) | VAF 31/298 reads (10%) | catalogued as rs202127683; called by muse, mutect2, varscan2
- OTOP1 | c.804C>T p.Y268= | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as rs1284885800; called by muse, mutect2, varscan2
- OVGP1 | c.1053G>A p.G351= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs761398748; called by muse, mutect2, varscan2
- OXTR | c.54C>A p.A18= | Silent (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- PALLD | c.177C>T p.D59= | Silent (SNP) | VAF 84/329 reads (26%) | catalogued as rs1199653834; called by muse, mutect2
- PAPPA2 | c.741C>T p.S247= | Silent (SNP) | VAF 56/436 reads (13%) | called by muse, mutect2, varscan2
- PCDH17 | c.2940T>A p.A980= | Silent (SNP) | VAF 150/319 reads (47%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1608G>T p.A536= | Silent (SNP) | VAF 235/739 reads (32%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1224A>G p.R408= | Silent (SNP) | VAF 46/252 reads (18%) | called by muse, mutect2, varscan2
- PIM2 | c.793C>A p.R265= | Silent (SNP) | VAF 35/235 reads (15%) | catalogued as COSV55943691; called by muse, mutect2, varscan2
- PKD2 | c.2661G>T p.G887= | Silent (SNP) | VAF 84/304 reads (28%) | catalogued as rs1357696307; called by muse, mutect2, varscan2
- PLXNA3 | c.1048C>A p.R350= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as COSV63756226; called by muse, mutect2, varscan2
- POLI | c.903A>T p.S301= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV54191088; called by muse, mutect2, varscan2
- PRF1 | c.1395G>T p.L465= | Silent (SNP) | VAF 91/260 reads (35%) | called by muse, mutect2, varscan2
- PRR16 | c.126C>A p.G42= | Silent (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- PTPN21 | c.1971A>T p.L657= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as rs1397505459; called by muse, mutect2, varscan2
- PTPRZ1 | c.3459T>A p.S1153= | Silent (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- RASSF9 | c.504G>A p.L168= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs1175473632; called by muse, mutect2, varscan2
- RFX1 | c.2832G>A p.A944= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs1465473446; called by muse, mutect2
- RGPD3 | c.2217C>A p.P739= | Silent (SNP) | VAF 39/302 reads (13%) | called by muse, mutect2, varscan2
- RIMS1 | c.4665G>T p.V1555= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- RXFP3 | c.156G>T p.L52= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100347884; called by muse, mutect2, varscan2
- SALL3 | c.138G>T p.G46= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, varscan2
- SCN4A | c.3858C>A p.T1286= | Silent (SNP) | VAF 46/158 reads (29%) | called by muse, mutect2, varscan2
- SHANK1 | c.1788C>G p.V596= | Silent (SNP) | VAF 12/362 reads (3%) | catalogued as COSV99521708; called by muse, mutect2
- SHPRH | c.4455A>G p.K1485= (on ENST00000275233 / NM_001042683.3; = p.K1489= on NM_173082.3) | Silent (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.4872G>T p.L1624= | Silent (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2, varscan2
- SLC12A6 | c.1851G>A p.G617= (on ENST00000354181 / NM_001365088.1; = p.G566= on NM_005135.2) | Silent (SNP) | VAF 81/417 reads (19%) | called by muse, mutect2, varscan2
- SLC25A43 | c.663C>A p.P221= | Silent (SNP) | VAF 56/176 reads (32%) | called by muse, mutect2, varscan2
- SLC5A10 | c.1266C>G p.G422= (on ENST00000395645 / NM_001042450.4; = p.G438= on NM_152351.5) | Silent (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- SLC6A15 | c.1314G>C p.G438= | Silent (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- SLIT3 | c.1548G>T p.V516= | Silent (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- SNTG2 | c.879T>A p.P293= | Silent (SNP) | VAF 60/220 reads (27%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2266C>T p.L756= | Silent (SNP) | VAF 257/531 reads (48%) | called by muse, mutect2, varscan2
- ST6GALNAC5 | c.954A>G p.P318= | Silent (SNP) | VAF 37/193 reads (19%) | catalogued as rs1164001118; called by muse, mutect2, varscan2
- TAF3 | c.1287G>T p.P429= | Silent (SNP) | VAF 44/183 reads (24%) | called by muse, mutect2, varscan2
- TAS2R16 | c.135G>A p.V45= | Silent (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- TEX13B | c.429G>T p.R143= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs943290810; called by muse, mutect2, varscan2
- TEX13C | c.1641G>T p.L547= | Silent (SNP) | VAF 152/486 reads (31%) | catalogued as COSV104373799; called by muse, varscan2
- TFCP2 | c.942A>G p.P314= | Silent (SNP) | VAF 45/129 reads (35%) | called by muse, mutect2, varscan2
- TIAM1 | c.795C>A p.P265= | Silent (SNP) | VAF 58/321 reads (18%) | called by muse, mutect2, varscan2
- TLN1 | c.1794G>C p.L598= | Silent (SNP) | VAF 64/174 reads (37%) | called by muse, mutect2, varscan2
- TLR10 | c.1272C>A p.V424= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- TMCO5A | c.786G>T p.L262= | Silent (SNP) | VAF 91/237 reads (38%) | called by muse, mutect2, varscan2
- TMEM164 | c.762C>A p.I254= (on ENST00000372068 / NM_032227.4; = p.I105= on NM_017698.2) | Silent (SNP) | VAF 98/333 reads (29%) | catalogued as COSV55812398; called by muse, mutect2, varscan2
- TMEM18 | c.6G>T p.P2= | Silent (SNP) | VAF 83/270 reads (31%) | called by muse, mutect2, varscan2
- TMTC4 | c.1269G>T p.V423= (on ENST00000376234 / NM_001350577.2; = p.V442= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- TNN | c.2040G>T p.P680= | Silent (SNP) | VAF 44/477 reads (9%) | catalogued as rs769031710, COSV53427039; called by muse, mutect2
- TNNI3K | c.2019G>A p.A673= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as rs138685516; called by muse, mutect2, varscan2
- TRIM50 | c.654C>T p.T218= | Silent (SNP) | VAF 38/301 reads (13%) | called by muse, mutect2, varscan2
- TSGA13 | c.771C>A p.A257= | Silent (SNP) | VAF 38/267 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.16642C>T p.L5548= (on ENST00000591111; = p.L4621= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/202 reads (25%) | catalogued as rs1255975692; called by muse, mutect2, varscan2
- TXNDC11 | c.1359T>A p.T453= (on ENST00000356957 / NM_001303447.2; = p.T426= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- VCAN | c.1077C>A p.L359= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV54104455, COSV99424865; called by muse, mutect2, varscan2
- VIT | c.1467C>A p.T489= (on ENST00000389975 / NM_001177969.1; = p.T504= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/244 reads (27%) | catalogued as rs200059174; called by muse, mutect2, varscan2
- VNN1 | c.645C>A p.L215= | Silent (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- VXN | c.171G>T p.L57= | Silent (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- WDR64 | c.396T>C p.D132= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- WNK4 | c.3567C>A p.L1189= | Silent (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- XKR3 | c.75T>C p.L25= | Silent (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- ZNF358 | c.1308C>T p.S436= | Silent (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- ZNF599 | c.267A>G p.T89= | Silent (SNP) | VAF 34/117 reads (29%) | called by muse, mutect2, varscan2
- ZXDA | c.1569T>C p.A523= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- AARS1 | c.1992+25C>T | Intron (SNP) | VAF 67/326 reads (21%) | catalogued as rs971554160; called by muse, mutect2, varscan2
- ABCA6 | c.2041+22G>T | Intron (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- ABCC8 | c.4307+167C>T | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- ABHD4 | chr14:22598190 C>A | 5'Flank (SNP) | VAF 76/176 reads (43%) | called by muse, varscan2
- AC007998.2 | c.157-7882G>T | Intron (SNP) | VAF 64/128 reads (50%) | called by muse, mutect2, varscan2
- AC009533.1 | n.734G>A | RNA (SNP) | VAF 130/457 reads (28%) | called by muse, mutect2, varscan2
- AC068473.1 | n.459G>T | RNA (SNP) | VAF 31/124 reads (25%) | called by muse, mutect2, varscan2
- AC136759.1 | n.531C>A | RNA (SNP) | VAF 65/271 reads (24%) | called by muse, mutect2, varscan2
- AC136759.1 | n.942G>A | RNA (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- ACSL6 | c.915+13G>A | Intron (SNP) | VAF 25/143 reads (17%) | catalogued as rs1259891233; called by muse, mutect2, varscan2
- ADRA2C | c.*206C>G | 3'UTR (SNP) | VAF 27/92 reads (29%) | catalogued as rs749128845; called by muse, mutect2, varscan2
- AKAP12 | c.320-6945C>A | Intron (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*623G>T | 3'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- ANXA3 | c.635-24T>G | Intron (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.3185-221G>A | Intron (SNP) | VAF 31/203 reads (15%) | catalogued as rs1466396735; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3916del | Intron (DEL) | VAF 66/235 reads (28%) | called by mutect2, pindel, varscan2
90 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 90 other) are not listed here.
